Gene-level copy-number profile of tumor specimen ALCH-B3ZR-TTP1-A from ALCHEMIST case ALCH-B3ZR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.8 years (24,036 days).
Specimen ALCH-B3ZR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e69b0631-a67a-48a3-a937-2fce2380e3bf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3ZR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/fb8fb5ce-a43c-4c5c-8f3f-0479c8d102f4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 85; copy number 1: 7,720; copy number 2: 49,388; copy number 3: 948; copy number 4: 247; copy number 5: 7; copy number 13: 3; copy number 33: 1.

Homozygous deletions (total copy number 0; autosomes only): 85 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:46,532,166–46,570,255, 3 genes (within-gene range 0–2): TMEM275, MKNK1-AS1, KNCN.
- chr1:53,459,399–53,467,488, 1 gene: DMRTB1.
- chr1:67,541,127–67,541,233, 1 gene: RNU6-1031P.
- chr2:85,751,344–85,791,383, 2 genes: ATOH8, MIR6071.
- chr2:97,713,576–97,739,862, 1 gene: ZAP70.
- chr3:41,955,445–41,955,763, 1 gene (within-gene range 0–2): RPL36P20.
- chr5:139,684,645–139,747,406, 3 genes: AC008667.1, RNU6-236P, PSD2-AS1.
- chr6:73,209,083–73,210,080, 1 gene (within-gene range 0–1): KHDC1P1.
- chr8:22,219,703–22,232,101, 1 gene: PHYHIP.
- chr9:61,190,003–61,453,030, 7 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr10:77,780,337–77,793,176, 2 genes (within-gene range 0–1): IMPDH1P5, AL450306.1.
- chr10:86,654,547–86,666,848, 1 gene: OPN4.
- chr10:93,060,798–93,077,885, 4 genes: CYP26C1, AL358613.3, AL358613.2, CYP26A1.
- chr15:25,184,306–25,250,940, 37 genes (within-gene range 0–2): SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:73,730,048–73,752,747, 2 genes (within-gene range 0–2): AC022188.1, INSYN1.
- chr15:93,035,273–93,089,204, 2 genes: RGMA, YBX2P2.
- chr16:33,907,419–33,976,346, 6 genes (within-gene range 0–3): ARHGAP23P1, IGHV3OR16-7, AC140658.4, IGHV3OR16-16, AC140658.1, AC140658.5.
- chr16:34,013,394–34,013,830, 1 gene: AC133561.2.
- chr17:38,419,280–38,512,385, 2 genes: ARHGAP23, AC244153.1.
- chr17:62,626,031–62,627,590, 2 genes (within-gene range 0–1): AC080038.2, AC080038.1.
- chr20:3,227,417–3,245,382, 2 genes: SLC4A11, AL109976.1.
- chr22:29,705,256–29,731,833, 3 genes (within-gene range 0–2): AC004882.1, AC004882.2, CABP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–58,915, 1 gene, copy number 5: AC113430.1.
- chr11:117,098,987–117,108,170, 1 gene, copy number 5: AP000936.1.
- chr17:42,199,177–42,276,707, 5 genes, copy number 5: STAT5B, AC099811.6, AC099811.4, AC099811.1, AC099811.5.
- chr21:43,414,483–43,479,534, 4 genes, copy number 13–33: SIK1, LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 6,790. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
